Gene-level copy-number profile of tumor specimen SM-JU346 from CPTAC case C761370, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen SM-JU346: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file eb338dd9-36ba-4b26-bc30-742914a510f3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105210 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/02f784b9-ec22-472e-98e1-65397780304b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8; copy number 2: 58,208; copy number 3: 44; copy number 4: 26; copy number 7: 1; copy number 8: 68; copy number 9: 48.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 117 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,542,325–57,485,895, 116 genes, copy number 8–9 (broad region; genes not listed).
- chr7:62,275,361–62,275,678, 1 gene, copy number 7: AC128676.1.

Autosomal genes at a single copy (total copy number 1): 8. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
